Somatic mutation profile of tumor specimen TCGA-UP-A6WW-01A (aliquot TCGA-UP-A6WW-01A-12D-A34J-08) from TCGA case TCGA-UP-A6WW, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; Tumor grade: G2; Age at diagnosis: 58.7 years (21,427 days).
Specimen TCGA-UP-A6WW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea9e3be7-c43d-42b3-9b8c-2adef6a4baab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UP-A6WW-10B (Blood Derived Normal), aliquot TCGA-UP-A6WW-10B-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe557660-39c4-4982-b85f-69ef6646dbfc

The open-access MAF lists 43 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 7, Intron 3, Frame Shift Ins 2, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PMS2 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 44/96 reads (46%) | catalogued as rs763939668, COSV56152280; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.3428C>T p.P1143L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs751858182, COSV99178930; called by muse, mutect2, varscan2
- ADCY1 | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs372552814; called by muse, mutect2, varscan2
- ANKRD35 | c.1549G>T p.V517F | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV100841746; called by muse, mutect2, varscan2
- CCDC51 | c.983A>T p.E328V | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV99602889; called by muse, mutect2, varscan2
- CPZ | c.1564C>T p.R522W (on ENST00000360986 / NM_001014447.3; = p.R511W on NM_003652.3) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs770247144, COSV100248991; called by muse, mutect2, varscan2
- DCAF1 | c.2635A>G p.T879A | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as COSV60044357; called by muse, mutect2
- DHRS7C | c.566G>A p.R189H (on ENST00000330255 / NM_001220493.2; = p.R188H on NM_001105571.3) | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs757672468, COSV57649744, COSV57651074; called by muse, mutect2, varscan2
- EQTN | c.40dup p.S14Ffs*5 | Frame Shift Ins (INS) | VAF 23/49 reads (47%) | catalogued as rs1378217410; called by mutect2, pindel, varscan2
- FBLN2 | c.3013T>C p.Y1005H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99851997; called by muse, mutect2, varscan2
- KAAG1 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.171); catalogued as COSV99219734; called by muse, mutect2
- KANK2 | c.2331G>A p.M777I (on ENST00000586659 / NM_001379562.1; = p.M785I on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100763229; called by muse, mutect2, varscan2
- KIF15 | c.3322A>T p.N1108Y | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV100392891; called by muse, mutect2, varscan2
- LONRF2 | c.1788T>G p.I596M | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66539727; called by muse, mutect2, varscan2
- MARCHF1 | c.311G>A p.R104H (on ENST00000274056; = p.R87H on NM_017923.4) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.036); catalogued as rs747281048, COSV56819371; called by muse, mutect2, varscan2
- OR2L2 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs138166879; called by muse, mutect2, varscan2
- OR6F1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs533401348, COSV100129227, COSV57468192; called by muse, mutect2, varscan2
- PDK3 | c.203C>G p.P68R | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64793916; called by muse, mutect2, varscan2
- PHF14 | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV101301810; called by muse, mutect2, varscan2
- PLEC | c.12343G>A p.D4115N (on ENST00000322810 / NM_201380.4; = p.D4005N on NM_000445.5) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369738267; called by muse, mutect2, varscan2
- PTGIS | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 113/276 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99721012; called by muse, mutect2, varscan2
- RHOBTB1 | c.2019A>C p.E673D | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100558492; called by muse, mutect2, varscan2
- RHPN2 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs752325119, COSV54274368; called by muse, mutect2, varscan2
- STK38L | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101198781; called by muse, mutect2, varscan2
- TRPM3 | c.2924T>C p.V975A (on ENST00000357533 / NM_001366142.2; = p.V818A on NM_020952.6) | Missense Mutation (SNP) | VAF 64/78 reads (82%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV100677477; called by muse, mutect2, varscan2
- UBOX5 | c.1398G>T p.W466C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.221); catalogued as COSV99417989; called by muse, mutect2, varscan2
- VXN | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100560011; called by muse, mutect2, varscan2
- ZNF107 | c.1983G>T p.E661D | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as rs1562849011, COSV61333015; called by muse, mutect2, varscan2
- ZNF197 | c.854A>G p.K285R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100482103; called by muse, mutect2, varscan2
- ZNF479 | c.42A>G p.G14= | Splice Region (SNP) | VAF 39/95 reads (41%) | catalogued as COSV100482768; called by muse, mutect2, varscan2
- IGHG1 | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 112/459 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TSPY1 | c.841T>C p.W281R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- USP9X | c.1092_1093insCACCTTA p.V365Hfs*12 | Frame Shift Ins (INS) | VAF 28/42 reads (67%) | called by mutect2, pindel*, varscan2
- ATP13A4 | c.3375C>T p.A1125= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs777706964, COSV100710389, COSV61321638; called by muse, mutect2
- EPHB1 | c.2007G>A p.A669= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs746250578, COSV101213209; called by muse, mutect2, varscan2
- SCN5A | c.1050C>T p.H350= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as rs587781160, COSV100348612; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- SVIL | c.5490G>A p.A1830= (on ENST00000355867 / NM_021738.3; = p.A1404= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs139597633, COSV100881424; called by muse, mutect2, varscan2
- TRAPPC9 | c.771C>T p.H257= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV101227567; called by muse, mutect2, varscan2
- UBE2O | c.3360C>T p.P1120= | Silent (SNP) | VAF 61/78 reads (78%) | catalogued as rs150209609, COSV100039355; called by muse, mutect2, varscan2
- USP43 | c.808C>T p.L270= | Silent (SNP) | VAF 153/194 reads (79%) | catalogued as COSV99556734; called by muse, mutect2, varscan2
- ISOC2 | c.349-25G>A | Intron (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99321202; called by muse, mutect2, varscan2
- LARP7 | c.1142+95G>A | Intron (SNP) | VAF 48/108 reads (44%) | catalogued as rs376629554; called by muse, mutect2, varscan2
- SLC39A14 | c.457+1511C>T | Intron (SNP) | VAF 65/170 reads (38%) | catalogued as rs762543092, COSV99249792; called by muse, mutect2, varscan2
